CCDI case PBCKPU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a8a183b0-04ce-40d2-84a0-5807f64b8e83

Demographics
Sex at birth: male.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,186 days).

Biospecimens (3 samples)
- Sample 0DWHZ3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWI19: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWI1U: Tissue type: Tumor; Specimen type: Solid Tissue.
